Somatic mutation profile of tumor specimen 0DFPU2 from CCDI case PBBRSW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 4.2 years (1,545 days).
Specimen 0DFPU2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ba58c33-1b13-4603-9049-0b35a73f2b66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFPU3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d591fbb-e501-42f9-80ee-42bedf4b492f

The open-access MAF lists 57 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Intron 8, 3'UTR 5, Frame Shift Del 2, Nonsense Mutation 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 271/530 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 79/628 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMPD2 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 66/339 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1472618505; called by muse, mutect2, varscan2
- BCL9L | c.2622G>T p.Q874H | Missense Mutation (SNP) | VAF 16/391 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs1008833116, COSV99419193; called by muse, mutect2
- HMGA1 | c.143C>T p.P48L (on ENST00000311487 / NM_001319082.2; = p.P37L on NM_002131.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/329 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs1174742693; called by muse, mutect2, varscan2
- MEGF6 | c.4214G>A p.R1405Q | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs567237600; called by muse, mutect2, varscan2
- MUC5AC | c.15847G>A p.G5283R | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs887447077, COSV100611461; called by muse, mutect2
- NRG1 | c.1637G>A p.R546Q (on ENST00000405005 / NM_013964.5; = p.R551Q on NM_013956.5) | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs141355195; called by muse, mutect2, varscan2
- OR5L2 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 42/563 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV101004217, COSV65723750; called by muse, mutect2
- PCDH11X | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 62/1032 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100015835, COSV53509311; called by muse, mutect2
- PRB1 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 136/672 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs762960285; called by mutect2, varscan2
- RYR2 | c.3391G>T p.D1131Y | Missense Mutation (SNP) | VAF 75/583 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV63659537, COSV63689837; called by muse, mutect2, varscan2
- TLE1 | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 126/516 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64723712; called by muse, mutect2, varscan2
- ADGRG4 | c.2126C>A p.P709Q | Missense Mutation (SNP) | VAF 30/590 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2
- ADGRL1 | c.4274C>G p.T1425S (on ENST00000340736 / NM_001008701.3; = p.T1420S on NM_014921.5) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by mutect2, varscan2
- BCL9 | c.1836C>G p.F612L | Missense Mutation (SNP) | VAF 102/594 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- DEFB116 | c.20G>C p.C7S | Missense Mutation (SNP) | VAF 188/1225 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EYS | c.2113T>G p.C705G | Missense Mutation (SNP) | VAF 212/755 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- GPRASP1 | c.2252C>G p.S751C | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- KIF7 | c.3040_3042del p.K1014del | In Frame Del (DEL) | VAF 32/120 reads (27%) | called by mutect2, varscan2
- KLB | c.2948_2949del p.T983Rfs*61 | Frame Shift Del (DEL) | VAF 143/584 reads (24%) | called by mutect2, varscan2
- MGAT4C | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 54/1187 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2
- NDNF | c.1406G>A p.W469* | Nonsense Mutation (SNP) | VAF 195/944 reads (21%) | called by muse, mutect2, varscan2
- PRDM10 | c.2811G>T p.Q937H | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.807); called by muse, mutect2
- SERPINE2 | c.846C>A p.S282R | Missense Mutation (SNP) | VAF 102/690 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- SLC7A2 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 108/658 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SLFN14 | c.2290T>A p.L764M | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SREBF1 | c.1546_1547del p.S516Rfs*8 | Frame Shift Del (DEL) | VAF 62/338 reads (18%) | called by mutect2, varscan2
- SYT13 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 66/380 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TJP2 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR62 | c.4258C>A p.Q1420K | Missense Mutation (SNP) | VAF 78/455 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- WNK3 | c.4817T>C p.V1606A | Missense Mutation (SNP) | VAF 160/623 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZMYM5 | c.1541T>G p.V514G | Missense Mutation (SNP) | VAF 77/370 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, mutect2
- FAM83A | c.1203G>T p.L401= | Silent (SNP) | VAF 13/275 reads (5%) | catalogued as COSV99414726; called by muse, mutect2
- GJA8 | c.381C>A p.G127= | Silent (SNP) | VAF 33/191 reads (17%) | called by muse, mutect2, varscan2
- NHLRC1 | c.513C>A p.A171= | Silent (SNP) | VAF 63/350 reads (18%) | called by muse, mutect2, varscan2
- NOSTRIN | c.1122G>A p.E374= (on ENST00000317647 / NM_001039724.4; = p.E296= on NM_052946.3) | Silent (SNP) | VAF 365/1045 reads (35%) | called by muse, mutect2, varscan2
- OR51D1 | c.703C>T p.L235= | Silent (SNP) | VAF 21/485 reads (4%) | called by muse, mutect2
- SEC31B | c.2739C>T p.S913= | Silent (SNP) | VAF 80/320 reads (25%) | catalogued as rs748277059; called by muse, mutect2, varscan2
- TRIM46 | c.1749C>T p.G583= | Silent (SNP) | VAF 45/231 reads (19%) | catalogued as rs1241837433, COSV58112122; called by muse, mutect2, varscan2
- USP17L2 | c.1353C>T p.N451= | Silent (SNP) | VAF 34/594 reads (6%) | catalogued as rs371227729; called by muse, mutect2
- WDHD1 | c.879G>C p.A293= | Silent (SNP) | VAF 33/532 reads (6%) | called by muse, mutect2
- CUEDC1 | c.1035-85G>T | Intron (SNP) | VAF 8/32 reads (25%) | catalogued as rs913198920; called by muse, mutect2
- GOLGA6L9 | c.265-77C>A | Intron (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- GPD1L | c.*48C>A | 3'UTR (SNP) | VAF 55/203 reads (27%) | called by muse, mutect2, varscan2
- ITGA3 | c.2071-15G>A | Intron (SNP) | VAF 78/344 reads (23%) | catalogued as rs1236852549, COSV99143206; called by muse, mutect2, varscan2
- MGAT4C | c.*34G>T | 3'UTR (SNP) | VAF 28/755 reads (4%) | called by muse, mutect2
- NAP1L2 | c.-1A>G | 5'UTR (SNP) | VAF 111/615 reads (18%) | called by muse, mutect2, varscan2
- POP7 | c.*42T>C | 3'UTR (SNP) | VAF 65/156 reads (42%) | called by muse, mutect2, varscan2
- PPP1R35 | c.234+35G>C | Intron (SNP) | VAF 28/203 reads (14%) | called by muse, mutect2, varscan2
- PRTG | c.*34C>T | 3'UTR (SNP) | VAF 19/233 reads (8%) | catalogued as rs371590764; called by muse, mutect2
- RAB17 | c.*40G>T | 3'UTR (SNP) | VAF 50/96 reads (52%) | called by muse, mutect2
- SRGAP1 | c.1408+95A>G | Intron (SNP) | VAF 30/112 reads (27%) | called by muse, mutect2, varscan2
- TMPRSS11B | c.508+39C>A | Intron (SNP) | VAF 110/330 reads (33%) | called by muse, mutect2, varscan2
- WDR97 | c.3105+15C>A | Intron (SNP) | VAF 19/338 reads (6%) | catalogued as rs1333433792; called by muse, mutect2
- WIPI2 | c.1122-30C>T | Intron (SNP) | VAF 10/72 reads (14%) | catalogued as rs369736104; called by muse, varscan2
